FM case AD7596 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/0bc09428-052b-4404-a48e-052d44276f1c

Female, 33.3 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the stomach; metastasis biopsied or resected from the cardia. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
